Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A8YR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A8YR-01A (Primary Tumor).

Name: [REDACTED]
Address: [REDACTED]
MR No.: [REDACTED]
Service: [REDACTED]
Surgeon: [REDACTED]

Surg. Path. No.: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])
Sex/Race: F WHITE
Location: [REDACTED]
Hosp. No.: [REDACTED]
Taken/Received: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX, BIOPSY - POORLY DIFFERENTIATED NON-KERATINIZING
SQUAMOUS CELL CARCINOMA (FRAGMENTS)

SPECIMEN(S) SUBMITTED
CERVIX BIOPSY

ICD-O-3

Carcinoma, squamous cell non-keratinizing NOS 8072/3

Site Cervix NOS C53.9

8/11/14

HISTORY

The patient is a [REDACTED] year old status post coital bleeding. Pap smear at outside hospital was Class IV. Operative procedure: Cervical biopsy to rule out squamous cell carcinoma.

GROSS

The specimen is received in a container of formalin, labelled with the patient's name and "cervical biopsy." It contains two fragments, measuring up 6 cm. One fragment contains likely squamous epithelium and transition zone. It is trisected. The other fragment is irregular and cannot be oriented with certainty. Jar O. [REDACTED]

COMMENT

Microscopic examination substantiates the above cited diagnosis.

(End of Report)

Gross Pathologist

Source: NCI Genomic Data Commons file a57bef8e-3753-4f44-b093-df80e99a1a10 (TCGA-C5-A8YR.C808B5E4-A426-4E68-9BFE-A98533562FD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).